Gene-level copy-number profile of tumor specimen ALCH-B25B-TTP1-A from ALCHEMIST case ALCH-B25B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,600 days).
Specimen ALCH-B25B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 441a7ca5-99ea-45bd-b6c0-f1cbb47e8931.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B25B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,321 have no estimate.
https://portal.gdc.cancer.gov/files/125c5a1b-c5d9-4f85-8dbf-dc5a0ded25c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 140; copy number 1: 9,538; copy number 2: 43,772; copy number 3: 3,169; copy number 4: 1,291; copy number 5: 326; copy number 6: 56; copy number 7: 6; copy number 8: 1; copy number 11: 1; copy number 12: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,773,738–12,777,906, 1 gene: PRAMEF12.
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–2): PRAMEF29P.
- chr1:13,222,705–13,248,652, 2 genes: PRAMEF18, PRAMEF31P.
- chr2:89,252,211–89,297,785, 7 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr2:89,947,512–89,960,754, 2 genes: IGKV2D-29, IGKV2D-28.
- chr3:48,663,776–48,686,364, 3 genes: LINC02585, AC141002.1, NCKIPSD.
- chr3:50,292,831–50,299,416, 2 genes (within-gene range 0–2): HYAL3, NAA80.
- chr3:75,328,549–75,371,342, 4 genes: MYLKP1, OR7E66P, OR7E22P, OR7E55P.
- chr3:75,415,070–75,435,110, 2 genes: ALG1L6P, FAM86DP.
- chr5:135,892,246–135,954,983, 5 genes (within-gene range 0–1): IL9, AC002428.2, AC002428.1, LECT2, FBXL21P.
- chr5:174,618,164–174,633,209, 2 genes: AC108112.1, HIGD1AP3.
- chr6:169,213,254–169,254,050, 2 genes (within-gene range 0–1): BX322234.1, THBS2.
- chr9:66,022,661–66,113,085, 5 genes (within-gene range 0–3): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.
- chr9:94,318,196–94,363,013, 4 genes (within-gene range 0–1): NUTM2F, AL691447.2, AL691447.1, PTMAP12.
- chr9:94,555,054–94,603,990, 2 genes (within-gene range 0–1): PCAT7, FBP2.
- chr9:95,599,438–95,715,718, 3 genes: AL392185.1, AL354861.2, AL354861.1.
- chr9:96,065,740–96,147,856, 4 genes: AL449403.1, Y_RNA, AL449403.2, EIF4BP3.
- chr9:96,246,462–96,256,319, 2 genes (within-gene range 0–1): HSD17B3-AS1, RNU6-1160P.
- chr9:107,458,038–107,490,482, 3 genes: HMGN2P32, RNU6-492P, KLF4.
- chr12:97,721,716–97,721,822, 1 gene (within-gene range 0–2): RNU6-36P.
- chr12:116,856,144–116,908,627, 2 genes: HRK, AC083806.1.
- chr12:122,167,738–122,203,471, 2 genes (within-gene range 0–1): LRRC43, IL31.
- chr12:125,138,245–125,151,394, 2 genes (within-gene range 0–1): AC122688.3, AC122688.2.
- chr12:126,864,465–126,888,718, 3 genes: AC078878.1, LINC02372, AC078878.2.
- chr12:127,758,832–127,826,286, 2 genes: AC087894.3, AC087894.2.
- chr12:128,187,225–128,244,573, 2 genes: AC061709.2, AC061709.1.
- chr12:130,419,535–130,430,661, 2 genes (within-gene range 0–1): AC063926.1, AC063926.3.
- chr12:130,980,667–130,993,976, 3 genes (within-gene range 0–1): AC073862.2, AC078925.4, ADGRD1-AS1.
- chr13:18,697,003–18,734,896, 4 genes: FAM207BP, GXYLT1P1, CNN2P12, ZNF965P.
- chr15:98,319,687–98,420,998, 2 genes: AC015722.2, LINC02351.
- chr16:51,017,544–51,038,764, 2 genes: LINC02127, AC027688.1.
- chr18:47,285,725–47,594,550, 4 genes: MIR4527HG, MIR4527, AC102797.2, AC102797.1.
- chr18:51,612,639–51,688,209, 2 genes: RSL24D1P9, AC027216.1.
- chr18:77,622,552–77,633,360, 2 genes: AC123786.1, AC123786.2.
- chr18:78,795,612–78,928,494, 4 genes: AC044873.1, AC091027.2, AC091027.1, AC091027.3.
- chr19:14,950,034–15,023,276, 2 genes: SLC1A6, CCDC105.
- chr19:22,555,261–22,596,163, 2 genes: RNU6-1179P, AC011467.5.
- chr19:22,615,552–22,623,971, 2 genes: LINC01785, AC011467.2.
- chr19:22,902,538–22,925,547, 2 genes: AC022145.1, AC022145.2.
- chr19:23,068,473–23,147,221, 6 genes: AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 392 genes in 93 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,489,860–120,842,110, 5 genes, copy number 5 (within-gene range 3–5): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr1:149,754,301–149,886,652, 15 genes, copy number 5: AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21.
- chr1:150,560,202–150,629,612, 7 genes, copy number 6 (within-gene range 4–6): ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr1:198,638,457–198,757,476, 3 genes, copy number 5: PTPRC, AL157402.2, PEBP1P3.
- chr3:112,921,205–113,019,861, 4 genes, copy number 5 (within-gene range 3–5): CD200R1, AC074044.1, GTPBP8, NEPRO.
- chr3:114,314,500–115,147,288, 6 genes, copy number 5 (within-gene range 3–5): ZBTB20, AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2.
- chr3:122,317,609–122,892,416, 17 genes, copy number 5: HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035.
- chr3:125,225,669–125,375,325, 3 genes, copy number 5: ZNF148, DUTP1, DNAJB6P7.
- chr3:129,632,019–129,918,575, 6 genes, copy number 5: AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1.
- chr3:136,818,647–136,951,606, 5 genes, copy number 5 (within-gene range 4–5): SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1.
- chr3:141,267,353–141,729,405, 9 genes, copy number 5 (within-gene range 3–5): AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618.
- chr3:143,381,338–143,627,690, 4 genes, copy number 5: SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1.
- chr3:146,391,421–146,606,216, 6 genes, copy number 5 (within-gene range 4–5): PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:148,791,102–149,661,364, 28 genes, copy number 5–6 (within-gene range 4–6): CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1-IT1, WWTR1-AS1.
- chr3:149,812,770–150,050,788, 8 genes, copy number 5 (within-gene range 4–5): RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24.
- chr3:150,238,519–150,630,445, 8 genes, copy number 5–6: LINC01213, U2, LINC01214, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1.
- chr3:152,118,173–152,496,813, 6 genes, copy number 5: AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:153,067,278–153,200,017, 5 genes, copy number 5: HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P.
- chr3:156,671,862–156,817,062, 5 genes, copy number 5: TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4.
- chr3:157,146,508–157,174,040, 5 genes, copy number 6: CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146.
- chr3:158,644,527–158,732,489, 4 genes, copy number 5 (within-gene range 4–5): GFM1, LXN, AC080013.3, RARRES1.
- chr3:167,683,298–167,950,292, 7 genes, copy number 5: PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3.
- chr3:169,773,396–170,305,977, 21 genes, copy number 5: MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr3:171,941,607–172,831,229, 20 genes, copy number 5–6: AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:177,010,719–178,385,479, 19 genes, copy number 5–7 (within-gene range 4–7): MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1.
- chr3:178,960,121–179,240,093, 5 genes, copy number 5–6 (within-gene range 4–6): ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1.
- chr3:182,783,236–182,921,938, 4 genes, copy number 5: AC069431.1, ATP11B, AC069431.2, AC092953.2.
- chr3:183,447,608–183,812,624, 12 genes, copy number 5: LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1.
- chr3:187,668,912–188,890,671, 16 genes, copy number 5–6: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28.
- chr3:193,842,560–194,006,098, 4 genes, copy number 5 (within-gene range 4–5): LINC02038, LINC02026, AC024559.1, DPPA2P3.
- chr3:194,394,821–194,521,156, 5 genes, copy number 5: GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1.
- chr3:196,452,996–196,515,346, 4 genes, copy number 5: AC117490.1, RNF168, AC117490.2, SMCO1.
- chr3:197,737,179–197,888,436, 5 genes, copy number 5 (within-gene range 4–5): FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1.
- chr6:26,195,554–26,206,038, 7 genes, copy number 5: H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5.
- chr9:128,039,135–128,109,245, 4 genes, copy number 5 (within-gene range 2–5): AL360268.2, NAIF1, SLC25A25, AL360268.1.
- chr9:136,975,092–136,993,984, 4 genes, copy number 5: PTGDS, AL807752.7, LCNL1, PAXX.
- chr12:68,674,371–68,745,809, 4 genes, copy number 5: AC090061.1, RPL7P42, NUP107, KRT8P39.
- chr17:18,450,244–18,494,945, 5 genes, copy number 6–12: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.
- chr19:41,708,585–41,772,211, 3 genes, copy number 5 (within-gene range 3–5): CEACAM5, AC243967.1, CEACAM6.
- chr19:58,513,530–58,558,954, 6 genes, copy number 5–7: ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M.

Autosomal genes at a single copy (total copy number 1): 9,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
